Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D0, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D0-01A (Primary Tumor).

1CD-0-3

Adenocarcinoma, NOS 8140/3

Site Code: Sigmoid colon C18.7

1/10/11
fw

(First Tumor)

Tumor Site:	Sigmoid Distal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Poorly Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☐ No ☒ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2
Pathologist Comment:	

Source: NCI Genomic Data Commons file 1192234d-26a1-453b-a05d-ff073c88400b (TCGA-DM-A1D0.6F6B3572-6437-4BAB-8DCB-91CE61567612.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).